Gene-level copy-number profile of tumor specimen ALCH-B3EH-TTP1-A from ALCHEMIST case ALCH-B3EH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,203 days).
Specimen ALCH-B3EH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 941f900b-31f8-4c29-bd23-53ac2bc9cc26.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3EH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,302 have no estimate.
https://portal.gdc.cancer.gov/files/11634272-b7c8-41b7-a5f4-ca27defb6d3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,099; copy number 2: 54,575; copy number 3: 1,692; copy number 4: 357; copy number 5: 112; copy number 6: 148; copy number 7: 35; copy number 8: 86; copy number 9: 23; copy number 10: 100; copy number 11: 22; copy number 12: 5; copy number 13: 26; copy number 15: 29; copy number 16: 1; copy number 17: 5; copy number 18: 4; copy number 20: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 598 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:186,538,441–187,372,076, 39 genes, copy number 5: CRYGS, TBCCD1, DNAJB11, AC068631.1, AC068631.2, AC068631.3, AHSG, Metazoa_SRP, FETUB, HRG, AC109780.1, AC109780.2, KNG1, PSMD10P2, RNU6-1105P, GPS2P2, AC112907.3, EIF4A2, SNORD2, SNORA63B, MIR1248, SNORA81, SNORA63, SNORA4, RFC4, AC112907.1, LINC02043, AC112907.2, ADIPOQ, ADIPOQ-AS1, RPS20P14, AC007690.1, ST6GAL1, RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4.
- chr3:187,668,912–188,154,057, 12 genes, copy number 5 (within-gene range 2–5): SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr5:58,198–1,634,005, 60 genes, copy number 6: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr9:61,854,148–62,096,920, 1 gene, copy number 8 (within-gene range 1–8): FAM27C.
- chr9:136,754,386–136,758,543, 1 gene, copy number 5: LCN8.
- chr12:57,674,665–60,363,935, 53 genes, copy number 5–8: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1.
- chr12:61,708,259–62,279,150, 1 gene, copy number 6 (within-gene range 4–6): TAFA2.
- chr12:61,879,318–72,670,758, 221 genes, copy number 5–15 (within-gene range 2–15) (broad region; genes not listed).
- chr16:46,407–76,355, 4 genes, copy number 5: POLR3K, SNRNP25, RHBDF1, Z69720.2.
- chr16:525,155–554,636, 5 genes, copy number 5: LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1.
- chr16:589,357–667,833, 7 genes, copy number 6 (within-gene range 4–6): RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:678,504–679,777, 2 genes, copy number 6 (within-gene range 4–6): LINC02867, Z92544.2.
- chr16:2,682,523–2,709,030, 2 genes, copy number 5: KCTD5, AC092117.2.
- chr16:19,167,971–20,239,247, 26 genes, copy number 6–20 (within-gene range 3–20): SYT17, AC010494.1, CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139, AC092132.2, AC092132.1, SNRPEP3.
- chr16:20,359,175–20,925,006, 23 genes, copy number 5–6: PDILT, AC106796.1, ACSM5, AC137056.1, ACSM2A, AC137056.2, ACSM2B, AC141273.1, ACSM5P1, ACSM3, AC141273.3, AC141273.2, ACSM1, THUMPD1, AC004381.3, AC004381.4, AC004381.1, ERI2, RNU6-944P, REXO5, AC004381.2, DCUN1D3, LYRM1.
- chr16:21,526,824–23,574,389, 61 genes, copy number 8–18 (broad region; genes not listed).
- chr16:23,753,689–23,758,935, 2 genes, copy number 5: AC012317.2, CHP2.
- chr16:25,691,959–26,358,355, 9 genes, copy number 7: HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1.
- chr16:27,459,555–27,549,913, 1 gene, copy number 6: GTF3C1.
- chr19:1,103,926–1,106,791, 1 gene, copy number 5: GPX4.
- chr20:57,105,741–57,163,775, 4 genes, copy number 6: AL157414.2, AL157414.1, AL157414.4, AL157414.3.
- chr20:57,266,797–58,911,192, 48 genes, copy number 6–11: AL122058.1, Y_RNA, MIR4325, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2.
- chr20:61,953,546–62,388,520, 15 genes, copy number 6–11: MIR1257, AL137077.1, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21.

Autosomal genes at a single copy (total copy number 1): 1,092. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
